Somatic mutation profile of tumor specimen TCGA-2G-AALQ-01A (aliquot TCGA-2G-AALQ-01A-12D-A42Y-10) from TCGA case TCGA-2G-AALQ, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Tissue or organ of origin: Testis, NOS.
Specimen TCGA-2G-AALQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22b9d843-4e27-401e-b6d0-1f072cf6a65a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AALQ-10A (Blood Derived Normal), aliquot TCGA-2G-AALQ-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e42306b6-0d4e-4d2e-9e6d-a63a91aaaf9d

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 2, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NYNRIN | c.2489G>A p.R830Q | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.883); catalogued as rs540767530; called by muse, mutect2, varscan2
- RECQL4 | c.1256C>T p.P419L | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as rs1370377411; called by muse, mutect2, varscan2
- THSD1 | c.1824T>A p.D608E | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.938); catalogued as rs1188762199; called by muse, mutect2
- USP4 | c.2578G>C p.A860P | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.055); catalogued as COSV99649382; called by muse, mutect2, varscan2
- VSIG2 | c.456G>C p.Q152H | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.694); catalogued as COSV52518444; called by muse, mutect2, varscan2
- EYS | c.2896G>C p.D966H | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KMT5B | c.2116_2117del p.Q706Vfs*6 | Frame Shift Del (DEL) | VAF 40/130 reads (31%) | called by pindel, varscan2
- KPRP | c.1664G>A p.R555K | Missense Mutation (SNP) | VAF 5/138 reads (4%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.058); called by muse, mutect2
- PPP6R3 | c.1870G>C p.E624Q (on ENST00000393800 / NM_001352375.2; = p.E544Q on NM_018312.5) | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- RIF1 | c.5243G>C p.G1748A | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- RXFP2 | c.1710T>A p.N570K | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VWA7 | c.1018C>A p.L340I | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- GSPT1 | c.126G>T p.P42= (on ENST00000420576 / NM_001130007.2; = p.P180= on NM_002094.4) | Silent (SNP) | VAF 61/183 reads (33%) | catalogued as rs747461614; called by muse, mutect2, varscan2
- PSMC3 | c.490C>T p.L164= | Silent (SNP) | VAF 11/77 reads (14%) | called by muse, mutect2, varscan2
- FUS | c.1293-22G>A | Intron (SNP) | VAF 77/303 reads (25%) | called by muse, mutect2, varscan2
